TCGA case TCGA-14-1034 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Emory University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0078b0c4-68a9-483b-9aab-61156d263213

Demographics
Sex at birth: female; Age at index: 60 years; Vital status: Dead; Days to death: 485 days (1.3 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 60.3 years (22,029 days); Year of diagnosis: 1999; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Dexamethasone; Treatment intent type: Adjuvant; Days to treatment start: 8 days.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 54 days; Days to treatment end: 78 days; Treatment dose: 5,400 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Dexamethasone; Initial disease status: Progressive Disease; Days to treatment start: 282 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine Implant; Initial disease status: Progressive Disease; Days to treatment start: 448 days (1.2 years); Treatment dose: 8 Wafer.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 61.1 years (22,311 days); Days to diagnosis: 282 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 448 days (1.2 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 282 (post initial treatment): Progression or recurrence: Yes; Days to progression: 282 days.
- Days to follow up: 485 days (1.3 years); Disease response: With Tumor.
- Karnofsky performance status: 60; Timepoint: Prior to Adjuvant Therapy.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-14-1034-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-14-1034-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
  Slide TCGA-14-1034-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0.
- Sample TCGA-14-1034-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-14-1034-02B: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Longest dimension: 1.3; Intermediate dimension: 0.5; Shortest dimension: 0.3.
  Slide TCGA-14-1034-02B-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 0.
  Slide TCGA-14-1034-02B-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 0.
- Sample TCGA-14-1034-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 2: Pharmaceutical therapy drug name: Gliadel.
- Drug treatment 2, Route of administrations: Route of administration: Other (specify below).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 485 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 485 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 282 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-14-1034-01A-01D-0517-01): tumor purity 0.54, ploidy 3.95, whole-genome doublings 1.
Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-14-1034-02B-01D-2002-01): tumor purity 0.97, ploidy 1.78, whole-genome doublings 0.
